Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H8, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H8-01A (Primary Tumor).

[page 1 of 2]
IIFAA Discrepancy		☒
Prior Malignancy / History		☒
	11/30/11	

History Case Pathology Report

Department of Pathology,

Tt

DOB:

Sex: r

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) LEFT NECK, HIGHEST MOST JUGULAR FORAMEN LYMPH NODE:
Lymph node, no tumor.
- (B) RIGHT CAROTID SHEATH LYMPH NODE:
METASTATIC THYROID CARCINOMA IN LYMPH NODE.
FROZEN SECTION REPORT, METASTATIC THYROID CARCINOMA IN LYMPH NODE.
- (C) RIGHT NECK DISSECTION, LONG SUTURE AT LEVEL IV:
METASTATIC PAPILLARY CARCINOMA IN 5 OF 14 LYMPH NODES.
- (D) LEFT NECK DISSECTION, LEVEL II, III, IV AND V:
METASTATIC PAPILLARY CARCINOMA OF THYROID IN 3 OF 22 LYMPH NODES.
- (E) LEFT SUPERIOR THYROID GLAND BIOPSY:
Parathyroid tissue.
- (F) PARATHYROID FAT:
Parathyroid tissue.
- (G) MASS BENEATH RECURRENT LARYNGEAL NERVE:
METASTATIC PAPILLARY CARCINOMA OF THYROID IN LYMPH NODE.
- (H) RULE OUT PARATHYROID TISSUE:
METASTATIC PAPILLARY CARCINOMA IN LYMPH NODE.
- (I) SUPERIOR MEDIAL STERNAL DISSECTION, TOTAL THYROIDECTOMY AND PARATRACHEAL LYMPH NODE DISSECTION:
PAPILLARY CARCINOMA OF THYROID INVOLVING THE LEFT LOBE WITH
EXTRAGLANDULAR EXTENSION INTO SOFT TISSUES.
X MICROSCOPIC FOCI OF PAPILLARY CARCINOMA OF THYROID IN RIGHT LOBE OF
THYROID.
METASTATIC PAPILLARY CARCINOMA IN 6 OF 8 PARATRACHEAL LYMPH NODES.

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid NOS C73.9 11/30/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

- (A) LEFT NECK HIGHEST MOST JUGULAR FORAMEN LYMPH NODE - Three lymph nodes ranging in size (0.6 x 0.5 x 0.3, and 0.3 x 0.2 x 0.2 cm). Specimen is entirely submitted in A.
- (B) RIGHT CAROTID SHEATH - Fragment of soft tissue 0.6 x 0.5 x 0.5 cm. Bisected and submitted entirely in B for frozen section examination.
- (C) RIGHT NECK DISSECTION, LONG SUTURE AT LEVEL IV - Fibroadipose tissue (14.0 x 3.0 x 2.0 cm). A stitch denoting "lower most" is provided. Multiple lymph nodes, the largest measuring 2.5 cm are identified. All lymph nodes are submitted from lower most to upper most.
SECTION CODE: C1, C2, one lymph node, multiple sections in two cassettes;

Page 1 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

[page 2 of 2]
History Case Pathology Report

Department of Pathology.

Tel.

DOB:

Sex: F

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

C3, one lymph node, bisected; C4, multiple lymph nodes; C5, C6, one lymph node, multiple sections in two cassettes (largest lymph node); C7, one lymph node, bisected; C8, one lymph node; C9, one lymph node.

(D) LEFT NECK, LEVEL II, III, IV, AND V - Fibroadipose tissue 15.0 x 2.0 x 1.0 cm. A stitch denoting "lower most" jugular node is provided.

Multiple lymph nodes are identified. The largest lymph node measures 2.0 cm in greatest dimension.

All lymph nodes are submitted from lower most to upper most. SECTION CODE:

D1, multiple lymph nodes; D2, multiple lymph nodes; D3, multiple lymph nodes; D4, multiple lymph node; D5, one lymph node; D6, one lymph node, bisected.

(E) LEFT SUPERIOR PARATHYROID GLAND BIOPSY - A piece of tan soft tissue (0.1 x 0.1 x 0.1 cm). Specimen totally submitted for frozen section in E.

(F) PARATHYROID FAT - A minute fragment of tissue, 0.1 x 0.1 x 0.1 cm. In toto in F for frozen section examination.

(G) MASS BENEATH RECURRENT LARYNGEAL NERVE AT MEMBRANE - A fragment of light tan soft tissue, 0.9 x 0.5 x 0.5 cm.

In toto in G for frozen section examination.

0.2 x 0.2 cm. specimen entirely submitted

(H) RULE OUT PARATHYROID TISSUE -

*FS/DX: METASTATIC THYROID CARCINOMA.

(I) SUPERIOR MEDIAL STERNAL DISSECTION, TOTAL THYROIDECTOMY - A paratracheal lymph node dissection present consists of the thyroid gland attached with a piece of fibroadipose tissue. The whole specimen is 10.5 x 6.8 x 2.5 cm. The left and right thyroid lobe MSF 3.5 x 2.5 x 2.2 cm. Attached to the inferior end of the thyroid is a piece of fibroconnective tissue 4.5 x 3.5 x 0.8 cm and within this the seven nodules measuring up to 1.0 cm in greatest dimension. A 2.0 x 1.7 x 1.2 cm nodule is present in one of the left thyroid lobe. The tumor has soft papillary cut surface. The remainder of the thyroid tissue is composed of red soft tissue with a slightly granular cut surface. The small nodule in the fibroconnective tissue appear to have a cut surface similar to the main tumor nodule.

INK CODE: Black - external surface of the thyroid.

SECTION CODE: I1-I5, one nodule, bisected, in each cassette from the fibroconnective tissue; I6, three possible lymph nodes from the fibroconnective tissue; I7-I11, left side tumor; I12-I14, nontumorous part of the thyroid.

SNOMED CODES

M-80503 M-80506 T-B6000 T-C4200

Source: NCI Genomic Data Commons file 681ba7d7-3506-4f5b-96c9-8e2951a8b62e (TCGA-EL-A3H8.62BDE4A8-A9F1-4CB5-9633-5F7C048F9845.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).